Somatic mutation profile of tumor specimen MMRF_2637_1_BM_CD138pos (aliquot MMRF_2637_1_BM_CD138pos_T1_KHS5U_L13318) from MMRF case MMRF_2637, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.5 years (20,279 days).
Specimen MMRF_2637_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 393e17c0-7344-4d3f-84dc-cc800575a2ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2637_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2637_1_PB_WBC_C3_KHS5U_L13319; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6276136-1df4-4323-9597-66b8be3fae0b

The open-access MAF lists 105 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 24, Intron 18, Silent 12, 5'UTR 7, 5'Flank 5, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376707472, COSV52390258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMN1 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 206/464 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs538283167; called by muse, mutect2, varscan2
- ARHGAP11A | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs374275026; called by muse, mutect2
- CEP83 | c.1157_1159del p.E386del | In Frame Del (DEL) | VAF 24/38 reads (63%) | catalogued as rs1486083035; called by pindel, varscan2
- CYP11B1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 183/471 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs200867786, COSV52824880, COSV52825943; called by muse, mutect2, varscan2
- FLRT3 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150799973; called by muse, mutect2, varscan2
- IGLL5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 42/90 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs550261872, COSV73249147; called by muse, varscan2
- IGLL5 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs189360394, COSV73248972; called by muse, varscan2
- MAF | c.131G>C p.S44T | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.584); catalogued as COSV58153826; called by muse, varscan2
- MAF | c.67A>G p.N23D | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1202221700; called by muse, varscan2
- MYCBP2 | c.11144G>A p.R3715Q (on ENST00000357337; = p.R3753Q on NM_015057.5) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62018941; called by muse, mutect2, varscan2
- NTN4 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV100643735, COSV59217807; called by muse, mutect2, varscan2
- PCNX2 | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 111/366 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs1388791937; called by muse, mutect2, varscan2
- STK36 | c.3260A>G p.H1087R | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1178202639; called by muse, mutect2
- TLL2 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as rs773230911; called by muse, mutect2, varscan2
- TTN | c.58146G>A p.M19382I (on ENST00000591111; = p.M11958I on NM_003319.4) | Missense Mutation (SNP) | VAF 44/338 reads (13%) | PolyPhen benign (0.013); catalogued as COSV100630666, COSV60300361; called by muse, mutect2, varscan2
- UBE3A | c.1204C>G p.P402A | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV99217710; called by muse, varscan2
- DAPK1 | c.4163C>T p.A1388V | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2
- EIF4EBP2 | c.358_360del p.I120del | In Frame Del (DEL) | VAF 60/146 reads (41%) | called by mutect2, pindel, varscan2
- ERN1 | c.653G>A p.W218* | Nonsense Mutation (SNP) | VAF 136/308 reads (44%) | called by muse, mutect2, varscan2
- FAM184A | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FURIN | c.1600A>G p.M534V | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HNRNPU | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGHV1-69D | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- IGLV3-1 | c.127_131del p.G43* | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | called by pindel, varscan2
- IGSF9B | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITSN2 | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- LEXM | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- MAF | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAF | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, varscan2
- MAF | c.275A>C p.Y92S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, varscan2
- NR2E3 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- PTPRM | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SPINT2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.353); called by muse, mutect2
- SRSF5 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- TBCK | c.967G>A p.E323K (on ENST00000273980 / NM_001163436.4; = p.E260K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM128 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE3A | c.1205C>A p.P402H | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, varscan2
- UGT8 | c.1589G>T p.R530I | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADCK2 | c.255C>A p.P85= | Silent (SNP) | VAF 16/217 reads (7%) | catalogued as rs773579650; called by muse, mutect2
- ATP10A | c.2976C>T p.L992= | Silent (SNP) | VAF 42/174 reads (24%) | catalogued as rs1230425975; called by muse, mutect2, varscan2
- DAXX | c.1191G>A p.R397= | Silent (SNP) | VAF 51/263 reads (19%) | catalogued as COSV56467262; called by muse, mutect2, varscan2
- DMRTA1 | c.324G>A p.A108= | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- EPHA5 | c.783C>A p.S261= | Silent (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- IGHV2-70 | c.213C>T p.L71= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as rs550291611; called by muse, varscan2
- MYO5C | c.3384G>T p.L1128= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- PHF2 | c.2796C>T p.T932= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs771510674; called by muse, mutect2, varscan2
- RAPGEFL1 | c.441C>T p.A147= | Silent (SNP) | VAF 12/243 reads (5%) | called by muse, mutect2
- TMEM221 | c.564G>A p.P188= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as rs1439585193; called by muse, mutect2, varscan2
- TTN | c.2505C>T p.A835= (on ENST00000591111; = p.A789= on NM_003319.4) | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs754725705, COSV60173613; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF799 | c.393T>C p.Y131= | Silent (SNP) | VAF 172/382 reads (45%) | called by muse, mutect2
- ADAD2 | c.559+112C>A | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- ANKRD40 | c.*340T>C | 3'UTR (SNP) | VAF 118/255 reads (46%) | called by muse, mutect2, varscan2
- ANO3 | c.*1012G>C | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505786 ins TTAA | 5'Flank (INS) | VAF 14/158 reads (9%) | called by mutect2, pindel
- ARHGEF26 | c.*75T>C | 3'UTR (SNP) | VAF 163/338 reads (48%) | catalogued as rs574238956; called by muse, varscan2
- BHLHE22 | c.-118G>A | 5'UTR (SNP) | VAF 19/34 reads (56%) | catalogued as rs1309528983; called by muse, mutect2, varscan2
- C10orf53 | c.*810A>T | 3'UTR (SNP) | VAF 57/136 reads (42%) | called by muse, mutect2, varscan2
- CACNB1 | c.*606T>G | 3'UTR (SNP) | VAF 75/156 reads (48%) | called by muse, mutect2, varscan2
- CAPN8 | c.307+11536G>A | Intron (SNP) | VAF 27/494 reads (5%) | called by muse, mutect2
- CLDN19 | c.*1044C>G | 3'UTR (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- DCAF5 | c.879+963A>G | Intron (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- DIP2C | c.85+37675C>T | Intron (SNP) | VAF 102/237 reads (43%) | called by muse, mutect2, varscan2
- DLX3 | c.*1406G>T | 3'UTR (SNP) | VAF 55/133 reads (41%) | called by muse, varscan2
- EFEMP1 | c.-7-138G>C | Intron (SNP) | VAF 72/153 reads (47%) | called by muse, mutect2, varscan2
- EIF2S3B | chr12:10505783 G>A | 5'Flank (SNP) | VAF 26/226 reads (12%) | called by muse, varscan2
- FIP1L1 | c.1175-1922C>T | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- GPX2 | chr14:64944178 A>C | 5'Flank (SNP) | VAF 28/64 reads (44%) | called by mutect2, varscan2
- GPX2 | chr14:64944179 C>T | 5'Flank (SNP) | VAF 28/63 reads (44%) | catalogued as rs1362008813; called by mutect2, varscan2
- GRHL1 | c.*120G>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- H1-0 | c.*153G>A | 3'UTR (SNP) | VAF 13/272 reads (5%) | called by muse, mutect2
- HEPHL1 | c.-12T>G | 5'UTR (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2
- IMPA2 | c.-108G>T | 5'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- KRT4 | c.834+128G>C | Intron (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- LTB | c.163-10A>G | Intron (SNP) | VAF 197/466 reads (42%) | called by muse, mutect2, varscan2
- MAF | c.*4357_*4359del | 3'UTR (DEL) | VAF 23/178 reads (13%) | catalogued as rs573865813; called by pindel, varscan2
- MAF | c.*1105T>A | 3'UTR (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- MAF | c.*1004T>C | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- MAF | c.-73G>T | 5'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- MAF | c.-120C>G | 5'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, varscan2
- MCAM | c.1912-73C>T | Intron (SNP) | VAF 28/47 reads (60%) | called by muse, mutect2, varscan2
- MCM7 | c.1849-226C>T | Intron (SNP) | VAF 39/147 reads (27%) | catalogued as COSV100385098; called by muse, mutect2, varscan2
- MGAT4A | c.*5128T>C | 3'UTR (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- MMRN1 | c.*719C>A | 3'UTR (SNP) | VAF 27/57 reads (47%) | catalogued as rs977518195; called by muse, mutect2, varscan2
- MYO15B | c.7227+54G>A | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- NCL | c.1447+193C>T | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as rs775675284; called by muse, mutect2, varscan2
- NRCAM | c.*808G>A | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- PABPC5 | c.*1176A>G | 3'UTR (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- PARD3B | c.2630+177A>T | Intron (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- PCDHA10 | c.2388+4575C>T | Intron (SNP) | VAF 54/127 reads (43%) | catalogued as rs782711409, COSV100249426; called by muse, mutect2, varscan2
- PLA2G2F | c.*561G>A | 3'UTR (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
- POLR2I | c.59+12G>A | Intron (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
- PRR14L | c.*3232C>T | 3'UTR (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.-221G>A | 5'UTR (SNP) | VAF 60/160 reads (38%) | catalogued as COSV59779204; called by muse, mutect2, varscan2
- RASGRF1 | c.3542+127A>T | Intron (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- RBMXL2 | c.*465A>G | 3'UTR (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.*1580C>T | 3'UTR (SNP) | VAF 10/35 reads (29%) | catalogued as rs1282682801; called by muse, mutect2, varscan2
- SCN3B | c.*2576dup | 3'UTR (INS) | VAF 28/52 reads (54%) | catalogued as rs746243185; called by mutect2, varscan2
- SGCZ | c.-194G>T | 5'UTR (SNP) | VAF 20/21 reads (95%) | called by muse, mutect2, varscan2
- SMAD7 | c.*1262G>A | 3'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- ST18 | c.1069+196T>A | Intron (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- SYNE2 | c.7377+43A>G | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- TENT5C | c.*3818_*3831del | 3'UTR (DEL) | VAF 15/19 reads (79%) | called by mutect2, varscan2
- TMSB4X | chrX:12975590 C>G | 5'Flank (SNP) | VAF 120/140 reads (86%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- ZNF527 | c.*3091T>C | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
